Gene-level copy-number profile of tumor specimen TCGA-04-1362-01A from TCGA case TCGA-04-1362, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIC; Tumor grade: G3; Age at diagnosis: 59.5 years (21,745 days).
Specimen TCGA-04-1362-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.8fcdd3d0-8a62-49aa-b7e2-5b06cb390d40.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1362-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/43a22a26-d3cb-47f5-9e6c-3148ff1ca4f5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 2,206; copy number 2: 22,499; copy number 3: 18,280; copy number 4: 9,356; copy number 5: 3,719; copy number 6: 2,626; copy number 7: 255; copy number 8: 748; copy number 9: 102; copy number 12: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1362-01A-01D-0452-01): tumor purity 0.86, ploidy 3.15, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,469 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–151,125,542, 295 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:173,338,219–176,823,653, 83 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr3:111,292,719–198,222,513, 1,582 genes, copy number 5–8 (within-gene range 4–8) (broad region; genes not listed).
- chr5:58,198–34,158,767, 521 genes, copy number 5–7 (broad region; genes not listed).
- chr5:160,249,083–160,345,396, 1 gene, copy number 5 (within-gene range 4–5): CCNJL.
- chr5:160,326,693–179,610,012, 337 genes, copy number 5 (broad region; genes not listed).
- chr6:2,916,894–7,881,728, 118 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:32,911,493–77,014,028, 696 genes, copy number 5–6 (broad region; genes not listed).
- chr8:84,864,668–145,066,685, 963 genes, copy number 6–12 (broad region; genes not listed).
- chr9:66,856,426–114,099,291, 787 genes, copy number 5 (broad region; genes not listed).
- chr11:61,897,301–88,045,608, 865 genes, copy number 6–7 (within-gene range 3–7) (broad region; genes not listed).
- chr11:121,979,571–135,075,908, 289 genes, copy number 5–6 (broad region; genes not listed).
- chr12:66,767–5,383,653, 134 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr12:27,780,048–42,996,486, 209 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr13:54,572,354–83,654,789, 256 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr14:22,011,910–22,509,406, 71 genes, copy number 6 (broad region; genes not listed).
- chr20:87,250–11,926,609, 262 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,206. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
